Somatic mutation profile of tumor specimen ER-AFAH-TTP1-A (aliquot ER-AFAH-TTP1-A-1-0-D-A629-34) from EXCEPTIONAL_RESPONDERS case ER-AFAH, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 48.3 years (17,659 days).
Specimen ER-AFAH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 934a509f-4b76-4605-8abf-996e3e85696c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AFAH-NT1-A (Solid Tissue Normal), aliquot ER-AFAH-NT1-A-1-0-D-A629-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c42217c-de8e-40ed-91f7-24b0145557f1

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Frame Shift Del 5, Nonsense Mutation 5, 3'UTR 4, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782789174, COSV54353275, COSV54356656; called by muse, mutect2, varscan2
- ADCY10 | c.2383C>T p.H795Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100896827; called by muse, mutect2, varscan2
- APC | c.4216del p.Q1406Rfs*9 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as CM023011, COSV57321535; called by mutect2, pindel, varscan2
- ARMCX1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.402); catalogued as rs781958602; called by muse, mutect2
- CACNA1C | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758229132, COSV59768190; called by muse, mutect2, varscan2
- CHST6 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381630371, COSV60000675; called by muse, mutect2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs749719822, COSV99752279; called by pindel, varscan2
- CNGB3 | c.21A>T p.K7N | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as rs778013546; called by muse, mutect2, varscan2
- CNTN5 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573111009, COSV54335334; called by mutect2, varscan2
- CNTN5 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as rs200726875, COSV54330869, COSV54362710; called by muse, varscan2
- COL5A1 | c.4714G>A p.V1572I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs543014323, CD133006; called by mutect2, varscan2
- CPSF2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs1350880939, COSV54099575; called by muse, mutect2, varscan2
- CPXCR1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as rs753571924, COSV52160820; called by muse, mutect2, varscan2
- DGKB | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as rs61753126, COSV51769726; called by muse, mutect2, varscan2
- ERBB4 | c.2638G>T p.G880* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV61489152; called by mutect2, varscan2
- FCHSD1 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1347027192; called by muse, mutect2, varscan2
- GPKOW | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782802093, COSV50242104; called by muse, mutect2, varscan2
- IFNA7 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as rs753809251; called by muse, varscan2
- KCNA1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838391; called by muse, varscan2
- KRT1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1555171169, COSV52867978; called by mutect2, varscan2
- NF1 | c.8138G>A p.R2713Q (on ENST00000358273 / NM_001042492.3; = p.R2692Q on NM_000267.3) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170836879, COSV62225863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CG | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs867282260, COSV100782716, COSV63249428; called by muse, mutect2, varscan2
- PRAMEF17 | c.341C>G p.T114S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.204); catalogued as COSV65816542; called by muse, mutect2, varscan2
- RNASE11 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100250503; called by muse, mutect2, varscan2
- SCAPER | c.2603dup p.N868Kfs*2 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | catalogued as rs1341630888; called by mutect2, varscan2
- SPEM1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs201288589, COSV100080794; called by muse, mutect2, varscan2
- SPO11 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61996213; called by muse, mutect2
- UROC1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs527715107; called by muse, mutect2, varscan2
- CADPS | c.2409dup p.G804Wfs*4 | Frame Shift Ins (INS) | VAF 30/329 reads (9%) | called by mutect2, pindel
- CD1E | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- CFAP70 | c.1090T>G p.Y364D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- COL4A1 | c.4787A>G p.Q1596R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.1525A>G p.I509V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FAM111B | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, varscan2
- FBH1 | c.1352A>C p.H451P (on ENST00000362091 / NM_178150.3; = p.H502P on NM_032807.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- GORAB | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GUCY1A1 | c.1850A>T p.N617I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADHA | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IL4R | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT2B | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- KCNMA1 | c.2428G>A p.D810N (on ENST00000286628 / NM_001161352.2; = p.D752N on NM_002247.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP3K8 | c.928_965del p.I310Gfs*34 | Frame Shift Del (DEL) | VAF 6/77 reads (8%) | called by mutect2, pindel
- MPPED2 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MR1 | c.716del p.N239Tfs*63 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- MSH5 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.251); called by muse, mutect2
- NFS1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOTCH1 | c.5999T>C p.I2000T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5W2 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- PNLIP | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2
- RPS16 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SACS | c.4583C>A p.S1528Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SLC2A10 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SPATS2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBX5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TFPI | c.307del p.M103Cfs*11 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, pindel, varscan2
- TNS3 | c.1076A>T p.K359M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- UBA1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP13 | c.813T>G p.Y271* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- WDR7 | c.3301A>T p.T1101S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WIPI2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, varscan2
- ZNF347 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF471 | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF615 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AASS | c.2532C>T p.I844= | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- ADAT3 | c.195C>T p.P65= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1402664883; called by muse, mutect2, varscan2
- ANGPT1 | c.1461T>G p.R487= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- BMT2 | c.1206A>G p.L402= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1368504280; called by muse, mutect2, varscan2
- FGD1 | c.147T>A p.G49= | Silent (SNP) | VAF 40/446 reads (9%) | called by muse, mutect2
- FGF9 | c.582C>T p.P194= | Silent (SNP) | VAF 31/299 reads (10%) | catalogued as rs750904852; called by muse, varscan2
- FOXF1 | c.1131C>T p.C377= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs776945484, COSV52285170, COSV52288743; called by mutect2, varscan2
- HID1 | c.1377C>T p.A459= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1478156522, COSV59351714; called by muse, mutect2, varscan2
- IRF9 | c.1119C>T p.A373= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- KSR2 | c.831G>A p.P277= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs752651619, COSV60365054; called by mutect2, varscan2
- MIDEAS | c.1911C>A p.P637= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99678772; called by muse, mutect2, varscan2
- OSBPL2 | c.90C>T p.V30= (on ENST00000313733 / NM_144498.4; = p.V18= on NM_014835.4) | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, varscan2
- PCDHA12 | c.1521C>T p.Y507= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- PCDHGA7 | c.1872C>T p.G624= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs568102289; called by mutect2, varscan2
- RASAL1 | c.741G>T p.L247= | Silent (SNP) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- SSTR5 | c.993C>T p.D331= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs750512306, COSV53512717; called by mutect2, varscan2
- THSD4 | c.792A>G p.E264= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99967179; called by muse, mutect2, varscan2
- TLR1 | c.1839G>A p.V613= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs749638831; called by muse, mutect2, varscan2
- TTN | c.1878A>G p.V626= (on ENST00000591111; = p.V580= on NM_003319.4) | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs761672925; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF275 | c.1215C>T p.C405= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1427671314, COSV100936147; called by muse, mutect2, varscan2
- ALG11 | c.*4435T>C | 3'UTR (SNP) | VAF 37/216 reads (17%) | called by muse, mutect2, varscan2
- GP6 | c.*55G>A | 3'UTR (SNP) | VAF 60/198 reads (30%) | catalogued as rs779914827; called by muse, mutect2, varscan2
- TRMT9B | c.*4232G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- Z83844.2 | c.*164C>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as rs1275638317; called by muse, mutect2, varscan2
